Gene-level copy-number profile of tumor specimen TCGA-4Z-AA86-01A from TCGA case TCGA-4Z-AA86, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 67.0 years (24,465 days).
Specimen TCGA-4Z-AA86-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.dcfc359a-fca7-4100-bc5c-4acdf9470ecb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-4Z-AA86-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f584f767-8de1-4d7d-ba15-fe88d20ec104

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,093; copy number 2: 29,415; copy number 3: 20,451; copy number 4: 6,599; copy number 5: 118; copy number 6: 367; copy number 7: 823; copy number 8: 117; copy number 9: 333; copy number 10: 200; copy number 12: 166; copy number 13: 61; copy number 15: 1; copy number 18: 13; copy number 23: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-4Z-AA86-01A-11D-A390-01): tumor purity 0.28, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,259 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,461,574–159,055,155, 25 genes, copy number 7 (within-gene range 3–7): OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2, OR6K3, OR6K4P, OR6K5P, OR6N1, OR6K6, OR6N2, OR2AQ1P, OR10AA1P, MNDA, PYHIN5P, PYHIN1, IFI16.
- chr1:159,759,170–189,133,292, 631 genes, copy number 6–13 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–7 (broad region; genes not listed).
- chr7:54,185,071–62,275,678, 157 genes, copy number 10–23 (broad region; genes not listed).
- chr17:31,303,770–34,174,964, 76 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr17:33,529,787–36,110,447, 117 genes, copy number 5 (broad region; genes not listed).
- chr17:39,461,486–39,864,312, 17 genes, copy number 7 (within-gene range 2–7): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr17:59,422,088–63,005,152, 109 genes, copy number 9–12 (within-gene range 4–12) (broad region; genes not listed).
- chr17:63,088,162–63,130,947, 2 genes, copy number 12: AC006270.2, AC006270.1.
- chr17:64,477,785–64,956,546, 33 genes, copy number 9: POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95, SMURF2, AC009994.1, MICOS10P2, ARHGAP27P1-BPTFP1-KPNA2P3, KPNA2P3, AC132812.1, BPTFP1, AC103810.3, PLEKHM1P1, MIR6080, MIR4315-2, RNU7-115P, AC103810.9, LRRC37A3, RN7SL404P, AC103810.6, AC103810.7, AC103810.2, AC103810.5, RDM1P4, AC103810.1, AC103810.4, AC037487.4, AC103810.8, AC037487.1, AC037487.3, SLC16A6P1.
- chr17:65,100,812–66,278,664, 12 genes, copy number 8–10 (within-gene range 2–10): RGS9, AC060771.1, LINC02563, AXIN2, AC004805.1, CEP112, AC004805.3, AC004805.2, PSMD7P1, APOH, RNA5SP444, AC009452.1.
- chr17:66,364,029–66,364,320, 1 gene, copy number 10: RN7SL735P.
- chr18:47,390–5,004,537, 101 genes, copy number 6–15 (within-gene range 2–15) (broad region; genes not listed).
- chr18:6,941,742–7,117,797, 1 gene, copy number 18 (within-gene range 2–18): LAMA1.
- chr18:7,076,817–15,330,282, 231 genes, copy number 8–18 (broad region; genes not listed).
- chr20:33,273,480–34,347,785, 35 genes, copy number 7 (within-gene range 4–7): BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1.
- chr20:34,384,165–34,384,265, 1 gene, copy number 7: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 1,085. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
